Gene-level copy-number profile of tumor specimen TCGA-BJ-A28W-01A from TCGA case TCGA-BJ-A28W, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.9 years (11,999 days).
Specimen TCGA-BJ-A28W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.40fd2b97-d7b0-4d0f-adf6-97fab00162d5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BJ-A28W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/402a6962-f705-4c2b-8fa9-5066c39f2f7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 144; copy number 2: 59,583; copy number 3: 1; copy number 5: 23; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:159,768,628–159,798,255, 1 gene (within-gene range 0–2): CD302.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:45,727,200–46,537,864, 23 genes, copy number 5 (within-gene range 2–5): WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr10:95,109,136–95,111,642, 1 gene, copy number 15: AL157834.1.

Autosomal genes at a single copy (total copy number 1): 144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
